Somatic mutation profile of tumor specimen 0E1SC7 from CCDI case PBCWNV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1SC7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c785d0e-e425-41b6-8be5-b65ef735a765.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1SBY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6de2ff13-7cc8-43ca-b5b2-aa8d4ef6a56c

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Translation Start Site 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPPK1 | c.8018G>A p.R2673Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1196872233; called by muse, mutect2, varscan2
- LRRC72 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as rs1365505033; called by muse, mutect2, varscan2
- PKN1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- C17orf80 | c.1533C>T p.S511= | Silent (SNP) | VAF 77/260 reads (30%) | called by muse, mutect2
- FGA | c.1197C>A p.G399= | Silent (SNP) | VAF 103/250 reads (41%) | called by muse, mutect2, varscan2
- GNPDA2 | c.324C>T p.D108= | Silent (SNP) | VAF 114/322 reads (35%) | catalogued as rs374535255; ClinVar: likely benign; called by muse, mutect2, varscan2
- UGT1A1 | c.360T>C p.S120= | Silent (SNP) | VAF 96/253 reads (38%) | called by muse, mutect2, varscan2
- ANKRD2 | c.-54C>G | 5'UTR (SNP) | VAF 119/324 reads (37%) | called by muse, mutect2, varscan2
- GCN1 | c.3630+34G>A | Intron (SNP) | VAF 50/183 reads (27%) | called by muse, mutect2, varscan2
